Somatic mutation profile of tumor specimen TCGA-37-A5EN-01A (aliquot TCGA-37-A5EN-01A-21D-A26M-08) from TCGA case TCGA-37-A5EN, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 59.1 years (21,600 days).
Specimen TCGA-37-A5EN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bda5df6f-c4cb-4d1b-a98a-4a0dc7cfd1c2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-37-A5EN-10A (Blood Derived Normal), aliquot TCGA-37-A5EN-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/87926f93-1cda-4a57-9b09-4abd1cc61e91

The open-access MAF lists 243 somatic variants for this specimen: 182 protein-altering or splice-affecting, 57 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 158, Silent 57, Nonsense Mutation 10, Frame Shift Del 5, Splice Site 4, Frame Shift Ins 3, Intron 1, 5'UTR 1, 3'UTR 1, RNA 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.733G>T p.G245C | Missense Mutation (SNP) | VAF 24/56 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB11 | c.3521T>A p.I1174N | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99791979; called by muse, mutect2
- ABCB8 | c.1250C>A p.A417D (on ENST00000297504 / NM_001282291.2; = p.A400D on NM_007188.5) | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99874236; called by muse, mutect2, varscan2
- ACO1 | c.385C>A p.Q129K | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV100008021; called by muse, varscan2
- ACOT12 | c.1555C>T p.P519S | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.045); catalogued as COSV100296868; called by muse, mutect2
- ADCY2 | c.1150G>T p.V384L | Missense Mutation (SNP) | VAF 60/125 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57868798, COSV57902234; called by muse, mutect2, varscan2
- AHNAK2 | c.7138G>T p.G2380C | Missense Mutation (SNP) | VAF 80/248 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100317023; called by muse, mutect2
- ANKRD17 | c.6587A>T p.Q2196L | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.775); catalogued as COSV100428967; called by muse, mutect2, varscan2
- ANKRD34A | c.747_748insA p.W250Mfs*14 | Frame Shift Ins (INS) | VAF 33/261 reads (13%) | catalogued as COSV100041211; called by mutect2, pindel, varscan2
- AQP6 | c.248C>T p.P83L | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100210145; called by muse, mutect2, varscan2
- ARHGAP20 | c.1074G>T p.M358I | Missense Mutation (SNP) | VAF 53/133 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV99503751; called by muse, mutect2, varscan2
- ASB17 | c.419A>G p.Y140C | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.994); catalogued as COSV99407899; called by muse, mutect2, varscan2
- ASIC2 | c.1196+1G>C p.X399_splice | Splice Site (SNP) | VAF 11/44 reads (25%) | catalogued as COSV56754829; called by muse, mutect2, varscan2
- BBS4 | c.1011G>A p.M337I | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs1215271289, COSV51438597, COSV99166421; called by muse, mutect2, varscan2
- BCAN | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100228039; called by muse, mutect2, varscan2
- BOLA1 | c.82dup p.A28Gfs*38 | Frame Shift Ins (INS) | VAF 31/90 reads (34%) | catalogued as rs782418502; called by mutect2, pindel, varscan2
- CDH12 | c.2011C>A p.Q671K | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as COSV101202240; called by muse, mutect2, varscan2
- CELF1 | c.186T>G p.C62W | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100136839; called by muse, mutect2, varscan2
- CHRM3 | c.1075T>A p.S359T | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.56); PolyPhen benign (0.042); catalogued as COSV99698088; called by muse, mutect2, varscan2
- CNGB3 | c.241G>T p.D81Y | Missense Mutation (SNP) | VAF 25/154 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV100181788; called by muse, mutect2, varscan2
- CNTNAP4 | c.2152G>C p.D718H | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.422); catalogued as COSV100270812; called by muse, mutect2, varscan2
- CNTNAP4 | c.3298G>A p.D1100N | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.61); PolyPhen probably damaging (1); catalogued as rs779291371, COSV100270815; called by muse, mutect2, varscan2
- COX6B1 | c.-12+6G>A | Splice Region (SNP) | VAF 36/164 reads (22%) | catalogued as COSV99876838; called by muse, mutect2, varscan2
- CRYAB | c.56C>A p.S19Y | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs537074990, COSV99909809; called by muse, mutect2
- CSMD1 | c.10635A>T p.K3545N (on ENST00000520002; = p.K3544N on NM_033225.6) | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV100146772; called by muse, mutect2, varscan2
- CSMD3 | c.5541G>C p.Q1847H (on ENST00000297405 / NM_001363185.1; = p.Q1743H on NM_052900.3) | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as COSV99831671; called by muse, mutect2, varscan2
- DAAM2 | c.1684C>A p.P562T | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.229); catalogued as COSV99225411; called by muse, mutect2
- DCDC1 | c.5199G>T p.M1733I (on ENST00000597505 / NM_001367979.1; = p.M840I on NM_020869.3) | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.05); PolyPhen benign (0.025); catalogued as COSV100360443; called by muse, mutect2, varscan2
- DENND2A | c.2734G>C p.G912R | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99325992; called by muse, mutect2, varscan2
- DNAH11 | c.10171A>G p.I3391V | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100176240; called by mutect2, varscan2
- DPH5 | c.77G>C p.C26S | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.36); PolyPhen benign (0.255); catalogued as COSV100587380; called by muse, mutect2, varscan2
- EDRF1 | c.2704T>G p.L902V (on ENST00000356792 / NM_001202438.2; = p.L868V on NM_015608.2) | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100523405; called by muse, mutect2, varscan2
- EEA1 | c.781C>T p.Q261* | Nonsense Mutation (SNP) | VAF 7/24 reads (29%) | catalogued as COSV100467475; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2486C>T p.S829L | Missense Mutation (SNP) | VAF 17/226 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.968); catalogued as rs951686169, COSV62569495; called by muse, mutect2
- EFCAB5 | c.1426C>T p.H476Y | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV57939080; called by muse, mutect2, varscan2
- ELP3 | c.1028G>A p.S343N | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV99833929; called by muse, mutect2, varscan2
- EML5 | c.1522G>A p.V508I | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100715441; called by muse, mutect2
- ENOX1 | c.1814A>T p.E605V | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99815685; called by muse, mutect2, varscan2
- ENOX1 | c.1087G>T p.D363Y | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99815686; called by muse, mutect2, varscan2
- ENOX1 | c.1086G>T p.W362C | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54892358; called by muse, mutect2, varscan2
- EVI2A | c.140T>C p.I47T | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99907567; called by muse, mutect2, varscan2
- EYA2 | c.749G>A p.R250Q | Missense Mutation (SNP) | VAF 51/140 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs377025058; called by muse, mutect2, varscan2
- FAT3 | c.12734C>A p.S4245Y | Missense Mutation (SNP) | VAF 10/226 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV53097017, COSV99964867; called by muse, mutect2
- FAT4 | c.12196G>A p.A4066T | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100628275; called by muse, mutect2, varscan2
- FGF8 | c.443C>T p.T148M (on ENST00000344255 / NM_033164.4; = p.T130M on NM_006119.6) | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs150575389; called by muse, mutect2, varscan2
- FOXD4L5 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 35/335 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV101073109; called by muse, mutect2, varscan2
- FRY | c.636-2A>T p.X212_splice | Splice Site (SNP) | VAF 25/103 reads (24%) | catalogued as COSV100969108; called by muse, mutect2, varscan2
- FSHR | c.130C>A p.L44I | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.029); catalogued as COSV99065634; called by muse, mutect2, varscan2
- GABBR1 | c.2245G>C p.D749H | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.833); catalogued as COSV100589624; called by muse, mutect2
- GDA | c.770G>A p.S257N | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs957687660, COSV99429117; called by muse, mutect2, varscan2
- GPCPD1 | c.1224A>C p.L408F | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100980152; called by muse, mutect2
- GPR32 | c.356C>T p.T119I | Missense Mutation (SNP) | VAF 49/80 reads (61%) | SIFT tolerated (0.22); PolyPhen benign (0.088); catalogued as COSV99567145; called by muse, mutect2, varscan2
- GRIA4 | c.368C>A p.P123H | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99230675; called by muse, mutect2, varscan2
- GRID2 | c.2516C>A p.A839D | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99939674; called by muse, mutect2, varscan2
- GRTP1 | c.461G>A p.C154Y | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100391119; called by muse, mutect2
- GTF3C2 | c.94A>G p.N32D | Missense Mutation (SNP) | VAF 43/238 reads (18%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV99272627; called by muse, mutect2, varscan2
- H1-8 | c.25G>A p.D9N | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.8); PolyPhen benign (0.106); catalogued as rs1197433314, COSV100180431; called by muse, mutect2, varscan2
- HNRNPLL | c.1351C>G p.P451A | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.326); catalogued as COSV99696524; called by muse, mutect2, varscan2
- HSD17B12 | c.864G>A p.W288* | Nonsense Mutation (SNP) | VAF 6/59 reads (10%) | catalogued as COSV99550590; called by muse, mutect2, varscan2
- HYDIN | c.14565G>C p.E4855D | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.569); catalogued as COSV101125037; called by muse, mutect2, varscan2
- IPO4 | c.1370A>G p.K457R | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.022); catalogued as COSV99937929; called by muse, mutect2, varscan2
- ITCH | c.371G>A p.G124D | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.86); catalogued as COSV99392319; called by muse, mutect2, varscan2
- ITGA8 | c.1903-1G>C p.X635_splice | Splice Site (SNP) | VAF 9/23 reads (39%) | catalogued as COSV100959122; called by muse, mutect2, varscan2
- JAKMIP2 | c.838-2A>G p.X280_splice | Splice Site (SNP) | VAF 13/23 reads (57%) | catalogued as COSV99508028; called by muse, mutect2, varscan2
- KCNA1 | c.427C>G p.P143A | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV101230194; called by muse, mutect2, varscan2
- KCND1 | c.1038T>A p.Y346* | Nonsense Mutation (SNP) | VAF 7/20 reads (35%) | catalogued as COSV99501905; called by mutect2, varscan2
- KEAP1 | c.703G>T p.D235Y | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV99407412, COSV99407659; called by muse, mutect2
- KIF5C | c.657G>C p.E219D | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.176); catalogued as COSV68481820; called by muse, mutect2, varscan2
- KLF12 | c.240G>C p.E80D | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.899); catalogued as COSV100888474; called by muse, mutect2, varscan2
- KMT2D | c.15751G>T p.E5251* | Nonsense Mutation (SNP) | VAF 37/130 reads (28%) | catalogued as COSV56422800, COSV56424851; called by muse, mutect2, varscan2
- LAGE3 | c.235C>T p.H79Y | Missense Mutation (SNP) | VAF 51/74 reads (69%) | SIFT tolerated (1); PolyPhen benign (0.313); catalogued as COSV62074396; called by muse, mutect2, varscan2
- LEFTY1 | c.132C>A p.D44E | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.287); catalogued as COSV55283160, COSV99686496; called by muse, mutect2
- LMO1 | c.170G>T p.R57L | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV100230906; called by muse, mutect2, varscan2
- LRRIQ4 | c.803G>T p.R268L | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0.025); catalogued as rs1187255870, COSV100540196; called by muse, mutect2, varscan2
- MAJIN | c.424C>T p.R142* | Nonsense Mutation (SNP) | VAF 37/101 reads (37%) | catalogued as rs768821510, COSV57263586; called by muse, mutect2, varscan2
- MLLT10 | c.2018A>G p.N673S (on ENST00000307729 / NM_001195626.3; = p.N689S on NM_004641.3) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV100307935, COSV56993274; called by muse, mutect2, varscan2
- MRGPRX2 | c.244C>G p.Q82E | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.191); catalogued as COSV100316713, COSV61674167; called by muse, mutect2, varscan2
- MS4A14 | c.867G>A p.M289I | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV100280301; called by muse, mutect2, varscan2
- MS4A2 | c.669C>A p.N223K | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.227); catalogued as COSV99627186; called by muse, mutect2
- MTA1 | c.1415A>G p.Y472C | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.827); catalogued as COSV100495092; called by muse, mutect2, varscan2
- MUC16 | c.4520G>T p.S1507I | Missense Mutation (SNP) | VAF 60/121 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.355); catalogued as COSV101199499; called by muse, mutect2, varscan2
- MYO16 | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1210280707, COSV51785631; called by muse, mutect2, varscan2
- MYO18B | c.6845A>G p.Q2282R | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.069); catalogued as COSV100123356; called by muse, mutect2, varscan2
- MYO7B | c.5204G>A p.W1735* | Nonsense Mutation (SNP) | VAF 12/57 reads (21%) | catalogued as COSV101268086; called by muse, mutect2
- NHEJ1 | c.209C>A p.A70E | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as COSV55406283, COSV99841052; called by muse, mutect2, varscan2
- NPAP1 | c.2084T>A p.I695N | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.096); catalogued as rs750616717, COSV100275215; called by muse, mutect2, varscan2
- NPAS3 | c.2771C>A p.A924E (on ENST00000356141 / NM_001164749.2; = p.A892E on NM_022123.3) | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.027); catalogued as COSV100640159, COSV60866732; called by muse, mutect2, varscan2
- NRAP | c.2783C>A p.A928E (on ENST00000359988 / NM_001322945.2; = p.A893E on NM_006175.4) | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.704); catalogued as COSV100748393; called by muse, mutect2, varscan2
- OR10R2 | c.58C>A p.Q20K | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV63768732; called by muse, mutect2, varscan2
- OR1L6 | c.172C>T p.P58S (on ENST00000373684; = p.P22S on NM_001004453.2) | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV100490864; called by muse, mutect2, varscan2
- OR2AK2 | c.98C>A p.T33N | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.07); catalogued as COSV100823445; called by muse, mutect2, varscan2
- OR4C6 | c.821C>A p.S274* | Nonsense Mutation (SNP) | VAF 38/88 reads (43%) | catalogued as COSV100051578; called by muse, mutect2, varscan2
- OR4K17 | c.272T>A p.V91E | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as COSV100210619; called by muse, mutect2, varscan2
- OR6N2 | c.169A>T p.T57S | Missense Mutation (SNP) | VAF 47/170 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.08); catalogued as COSV100210076; called by muse, mutect2, varscan2
- OTOGL | c.1850T>C p.L617P (on ENST00000547103; = p.L608P on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101509165; called by muse, mutect2, varscan2
- PAX9 | c.154T>A p.C52S | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100825764; called by muse, mutect2, varscan2
- PAXIP1 | c.3127G>A p.G1043S | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs1382410799, COSV101249574; called by muse, mutect2, varscan2
- PCDHA1 | c.1501G>C p.E501Q | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.732); catalogued as rs782741902, COSV100974342, COSV65376249; called by muse, mutect2, varscan2
- PCLO | c.10232A>T p.K3411I | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV100430997; called by muse, mutect2, varscan2
- PER3 | c.957G>T p.M319I | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100728309; called by muse, mutect2, varscan2
- PHKG1 | c.228C>G p.D76E | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99818158; called by muse, mutect2, varscan2
- PIGQ | c.2114A>T p.Q705L | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); catalogued as COSV99215976; called by muse, mutect2, varscan2
- PLEKHA2 | c.1155G>T p.E385D | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV100205709; called by muse, mutect2
- POGLUT1 | c.266A>G p.Y89C | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55156652; called by muse, mutect2, varscan2
- POLR3A | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs771607996, COSV100965620; called by muse, mutect2, varscan2
- POTEH | c.406G>T p.G136C | Missense Mutation (SNP) | VAF 43/397 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.041); catalogued as COSV58879567; called by muse, varscan2
- PRKCQ | c.1180G>A p.V394I | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.408); catalogued as COSV99576731; called by muse, mutect2, varscan2
- PRSS53 | c.838C>T p.Q280* | Nonsense Mutation (SNP) | VAF 29/118 reads (25%) | catalogued as COSV99762218; called by muse, mutect2, varscan2
- PSMB6 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs1223360638; called by muse, mutect2
- PTPRB | c.2989T>C p.S997P | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV99717027; called by muse, mutect2, varscan2
- RAB11A | c.583G>A p.V195M | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.01); catalogued as COSV99976677; called by muse, mutect2, varscan2
- RABEP2 | c.1031T>C p.L344P | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100706954; called by muse, mutect2, varscan2
- RAD23B | c.677T>C p.L226S | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV100787680; called by muse, mutect2, varscan2
- RANBP2 | c.8158G>T p.V2720F | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV99311885; called by muse, varscan2
- REG3A | c.471G>C p.R157S | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV100532660, COSV100532997; called by muse, mutect2, varscan2
- RGS12 | c.1579G>A p.V527M | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs147592303; called by muse, mutect2, varscan2
- RGS22 | c.567G>A p.M189I | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.084); catalogued as COSV62667466; called by muse, mutect2, varscan2
- RIPOR2 | c.577A>T p.I193F | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.888); catalogued as COSV99428976; called by muse, mutect2, varscan2
- RYR2 | c.14377T>A p.Y4793N | Missense Mutation (SNP) | VAF 51/217 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100769579; called by muse, mutect2, varscan2
- RYR3 | c.2378G>T p.G793V | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101212537; called by muse, mutect2, varscan2
- SALL1 | c.2879T>C p.L960S | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.009); catalogued as COSV99173288; called by muse, mutect2, varscan2
- SCAF11 | c.2894G>C p.R965P | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101014263; called by muse, mutect2, varscan2
- SCN2A | c.2884G>T p.V962F | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.853); catalogued as COSV99331142, COSV99331552; called by muse, mutect2, varscan2
- SCN2A | c.5425G>A p.A1809T | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV99331147; called by muse, mutect2, varscan2
- SCN5A | c.263G>T p.S88I | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.806); catalogued as COSV100028322; called by muse, mutect2, varscan2
- SCN7A | c.4421T>C p.F1474S | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV101313174; called by muse, mutect2
- SEPTIN4 | c.703G>C p.D235H | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.853); catalogued as COSV100400310; called by muse, mutect2, varscan2
- SFXN4 | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as COSV100045346; called by muse, mutect2, varscan2
- SHANK2 | c.5358G>C p.W1786C | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53623682, COSV99573419; called by muse, mutect2, varscan2
- SI | c.3605C>T p.P1202L | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1054103291, COSV100015099, COSV52272868; called by muse, mutect2, varscan2
- SLC4A2 | c.1319G>T p.R440L | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV59656658; called by muse, mutect2, varscan2
- SORCS1 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as COSV99545392; called by muse, varscan2
- SQOR | c.1151G>T p.G384V | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as COSV99525691; called by muse, mutect2, varscan2
- STAB1 | c.7163A>C p.E2388A | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV100194791; called by muse, mutect2, varscan2
- SYNE1 | c.1709A>T p.Y570F (on ENST00000367255 / NM_182961.4; = p.Y577F on NM_033071.3) | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.406); catalogued as COSV99560952; called by muse, mutect2, varscan2
- TANK | c.50G>T p.R17L | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99376033; called by muse, mutect2, varscan2
- TAS2R19 | c.149C>G p.A50G | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.521); catalogued as COSV101114626, COSV66829203; called by muse, mutect2, varscan2
- TBC1D13 | c.68T>C p.L23S | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV99804411; called by muse, mutect2
- TBX5 | c.605G>T p.C202F | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as COSV100091048; called by muse, mutect2, varscan2
- TCHH | c.5747G>A p.G1916D | Missense Mutation (SNP) | VAF 43/140 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.792); catalogued as COSV100914990; called by muse, mutect2, varscan2
- TECTA | c.5270G>T p.C1757F | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV99879528; called by muse, mutect2, varscan2
- TET2 | c.988G>C p.E330Q | Missense Mutation (SNP) | VAF 25/35 reads (71%) | SIFT tolerated (0.22); PolyPhen benign (0.193); catalogued as COSV54411055, COSV54422740; called by muse, mutect2, varscan2
- THSD7A | c.1699C>A p.P567T | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.742); catalogued as COSV101448656; called by muse, mutect2, varscan2
- TKTL1 | c.995G>A p.R332H | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs782301272, COSV99473898; called by muse, mutect2
- TMEM62 | c.521A>T p.H174L | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99543506; called by muse, mutect2, varscan2
- TP53BP1 | c.4372C>T p.R1458C | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as rs746329471, COSV99780322; called by muse, mutect2, varscan2
- TRMT6 | c.961A>G p.M321V | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs776097806, COSV52543408; called by muse, mutect2, varscan2
- TRPA1 | c.239A>C p.E80A | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as COSV100083863; called by muse, mutect2, varscan2
- TSHZ1 | c.1643G>T p.G548V (on ENST00000580243 / NM_001308210.2; = p.G503V on NM_005786.6) | Missense Mutation (SNP) | VAF 49/129 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100433570; called by muse, mutect2, varscan2
- TTC13 | c.863A>G p.Y288C | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV100792908; called by muse, mutect2
- TTC32 | c.44C>G p.A15G | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100367803; called by muse, mutect2
- TTLL2 | c.106A>T p.T36S | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV99514625; called by muse, mutect2, varscan2
- TTLL2 | c.1448C>T p.A483V | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.026); catalogued as rs773308142, COSV99514632; called by muse, mutect2, varscan2
- TTN | c.38843C>A p.T12948K (on ENST00000591111; = p.T5524K on NM_003319.4) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | PolyPhen probably damaging (0.951); catalogued as COSV100606679; called by muse, mutect2, varscan2
- TTN | c.2896A>G p.I966V (on ENST00000591111; = p.I920V on NM_003319.4) | Missense Mutation (SNP) | VAF 30/53 reads (57%) | PolyPhen benign (0.203); catalogued as COSV100606683; called by muse, mutect2, varscan2
- TYRP1 | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated (0.05); PolyPhen benign (0.394); catalogued as rs751545422, COSV101141273; called by muse, mutect2, varscan2
- UBR4 | c.5647C>T p.Q1883* | Nonsense Mutation (SNP) | VAF 13/177 reads (7%) | catalogued as COSV100920692; called by muse, mutect2
- UGT3A1 | c.1541T>A p.L514Q | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV57104179, COSV99954634; called by muse, mutect2, varscan2
- USH2A | c.14501C>A p.S4834Y | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as rs1052736072, COSV100233091; called by muse, mutect2, varscan2
- VASN | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0.009); catalogued as rs760768336, COSV52029934; called by muse, mutect2, varscan2
- WDR24 | c.442G>A p.D148N (on ENST00000248142; = p.D86N on NM_032259.4) | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as COSV99555606; called by muse, mutect2, varscan2
- WHAMM | c.2358G>C p.Q786H | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV99724837; called by muse, mutect2, varscan2
- ZDHHC6 | c.450A>T p.L150F | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV101024384; called by muse, mutect2, varscan2
- ZFC3H1 | c.4565G>A p.R1522Q | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as rs762358615, COSV66437108; called by muse, mutect2, varscan2
- ZFHX4 | c.6696A>T p.R2232S | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99261530; called by muse, mutect2, varscan2
- ZFX | c.425C>T p.S142F | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.12); catalogued as COSV100457530; called by muse, mutect2
- ZNF25 | c.1274C>T p.P425L | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.294); catalogued as rs1300182160, COSV100224582; called by muse, mutect2, varscan2
- ZNF337 | c.213G>A p.W71* | Nonsense Mutation (SNP) | VAF 33/255 reads (13%) | catalogued as rs759473859, COSV99430135; called by muse, mutect2, varscan2
- ZNF43 | c.2065C>G p.L689V | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.55); PolyPhen benign (0.041); catalogued as rs1406791608, COSV100731781; called by muse, mutect2, varscan2
- ZNF564 | c.1152G>A p.M384I | Missense Mutation (SNP) | VAF 9/202 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.045); catalogued as COSV100213087; called by muse, mutect2
- ZNF804B | c.3072C>A p.N1024K | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV100303209, COSV60856739; called by muse, mutect2, varscan2
- ZNF99 | c.1868G>T p.C623F | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.594); catalogued as COSV101233803, COSV101233918; called by muse, mutect2, varscan2
- CUEDC2 | c.445del p.V149Wfs*35 | Frame Shift Del (DEL) | VAF 19/48 reads (40%) | called by mutect2, varscan2
- FOXO3 | c.1230del p.S411Afs*30 | Frame Shift Del (DEL) | VAF 24/111 reads (22%) | called by mutect2, pindel, varscan2
- MOSPD2 | c.175_184dup p.L62Rfs*2 | Frame Shift Ins (INS) | VAF 10/24 reads (42%) | called by mutect2, varscan2
- NGEF | c.1846del p.Q616Rfs*16 | Frame Shift Del (DEL) | VAF 25/92 reads (27%) | called by mutect2, pindel, varscan2
- PILRA | c.269A>T p.H90L | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); called by muse, mutect2
- PRB3 | c.751C>A p.P251T (on ENST00000381842; = p.P293T on NM_006249.5) | Missense Mutation (SNP) | VAF 10/278 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.209); called by muse, mutect2
- PSD3 | c.1447_1473del p.Q483_Q491del | In Frame Del (DEL) | VAF 13/121 reads (11%) | called by mutect2, pindel
- SYCP1 | c.38del p.P13Rfs*11 | Frame Shift Del (DEL) | VAF 30/77 reads (39%) | called by mutect2, pindel, varscan2
- TASP1 | c.471_472delinsA p.G158Afs*8 | Frame Shift Del (DEL) | VAF 41/164 reads (25%) | called by pindel, varscan2*
- TBC1D3B | c.804C>G p.C268W | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by mutect2, varscan2
- ACO1 | c.312G>A p.V104= | Silent (SNP) | VAF 19/81 reads (23%) | catalogued as COSV100008013; called by muse, varscan2
- ADTRP | c.270G>T p.L90= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as COSV99995207; called by muse, mutect2
- ARL13B | c.819A>G p.R273= (on ENST00000394222 / NM_001174150.2; = p.R166= on NM_144996.4) | Silent (SNP) | VAF 12/22 reads (55%) | catalogued as COSV100115377; called by muse, mutect2, varscan2
- BICC1 | c.1260T>C p.S420= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as COSV99570434; called by muse, mutect2, varscan2
- BIRC6 | c.9015C>G p.A3005= | Silent (SNP) | VAF 39/71 reads (55%) | catalogued as rs1291608232, COSV101428157; called by muse, mutect2, varscan2
- CAV1 | c.153G>T p.L51= | Silent (SNP) | VAF 38/110 reads (35%) | catalogued as COSV100591900; called by muse, mutect2, varscan2
- CCDC89 | c.51G>A p.P17= | Silent (SNP) | VAF 10/101 reads (10%) | catalogued as rs751469071, COSV57034431; called by muse, mutect2
- CLNK | c.366G>A p.Q122= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV99904980; called by muse, mutect2, varscan2
- COL15A1 | c.2448G>C p.S816= | Silent (SNP) | VAF 14/127 reads (11%) | catalogued as rs760671676, COSV100897594, COSV66650213; called by muse, mutect2, varscan2
- CSMD2 | c.5796T>C p.S1932= | Silent (SNP) | VAF 20/35 reads (57%) | catalogued as COSV99588898; called by muse, mutect2, varscan2
- CSMD3 | c.1485G>C p.G495= (on ENST00000297405 / NM_001363185.1; = p.G391= on NM_052900.3) | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV99831674; called by muse, mutect2, varscan2
- DTX4 | c.1002C>T p.I334= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as COSV99915259; called by muse, mutect2, varscan2
- DTX4 | c.1509C>A p.I503= | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as COSV99915263; called by muse, mutect2, varscan2
- EXOC3L4 | c.1461G>A p.E487= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV101197599; called by muse, mutect2, varscan2
- FAM120C | c.3135G>A p.K1045= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as rs1557120257, COSV100069915; called by muse, mutect2, varscan2
- GREB1 | c.3825T>C p.S1275= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV99302755; called by muse, mutect2, varscan2
- GTSE1 | c.1623T>C p.L541= | Silent (SNP) | VAF 25/100 reads (25%) | catalogued as COSV101483205; called by muse, mutect2, varscan2
- GZMH | c.96C>T p.R32= | Silent (SNP) | VAF 47/214 reads (22%) | catalogued as COSV99361891; called by muse, mutect2, varscan2
- HIP1 | c.324G>C p.P108= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as COSV100417370; called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.99T>A p.P33= | Silent (SNP) | VAF 19/75 reads (25%) | called by muse, mutect2, varscan2
- IGKV1-8 | c.69G>T p.R23= | Silent (SNP) | VAF 31/219 reads (14%) | called by muse, mutect2, varscan2
- IL12RB1 | c.1530G>C p.L510= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV101651891; called by muse, mutect2, varscan2
- IL5RA | c.345T>C p.S115= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as rs1472880759, COSV99842898; called by muse, mutect2, varscan2
- KLHL11 | c.1227G>T p.V409= | Silent (SNP) | VAF 38/109 reads (35%) | catalogued as COSV100044287; called by muse, mutect2, varscan2
- MAGEC3 | c.1653T>C p.L551= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as COSV100025242; called by muse, mutect2, varscan2
- MPEG1 | c.930G>A p.L310= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as COSV99915265; called by muse, mutect2, varscan2
- MUC5B | c.10704C>T p.T3568= | Silent (SNP) | VAF 18/112 reads (16%) | catalogued as COSV101500261; called by muse, varscan2
- NAV3 | c.273A>T p.L91= | Silent (SNP) | VAF 22/103 reads (21%) | catalogued as rs528933776, COSV99889597; called by muse, mutect2, varscan2
- NCAM2 | c.1011T>G p.A337= | Silent (SNP) | VAF 15/19 reads (79%) | catalogued as COSV99522612; called by muse, mutect2, varscan2
- NRK | c.1411C>T p.L471= | Silent (SNP) | VAF 21/33 reads (64%) | catalogued as COSV99687435; called by muse, mutect2, varscan2
- OR10W1 | c.708C>G p.L236= | Silent (SNP) | VAF 15/98 reads (15%) | catalogued as COSV101223650, COSV67720862; called by muse, mutect2, varscan2
- OR4D10 | c.261T>C p.S87= | Silent (SNP) | VAF 17/92 reads (18%) | catalogued as COSV101597006; called by muse, mutect2, varscan2
- OR5AP2 | c.888T>C p.Y296= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs1460379344, COSV100266149; called by muse, mutect2, varscan2
- PCDHGA1 | c.786C>A p.L262= | Silent (SNP) | VAF 23/45 reads (51%) | catalogued as rs564015279, COSV65295425; called by muse, mutect2, varscan2
- PDE1C | c.285A>G p.E95= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as COSV101275513; called by muse, mutect2, varscan2
- PGAM4 | c.237G>T p.L79= | Silent (SNP) | VAF 10/102 reads (10%) | catalogued as COSV100430635; called by muse, mutect2, varscan2
- PIKFYVE | c.5370T>C p.P1790= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as COSV100010455; called by muse, mutect2, varscan2
- PRAG1 | c.4065C>T p.I1355= | Silent (SNP) | VAF 51/181 reads (28%) | catalogued as rs1156293459, COSV100422099; called by muse, mutect2, varscan2
- PRKCG | c.2016C>A p.G672= | Silent (SNP) | VAF 47/100 reads (47%) | catalogued as COSV99668877; called by muse, mutect2, varscan2
- PTGDR | c.564C>G p.V188= | Silent (SNP) | VAF 15/188 reads (8%) | catalogued as COSV100035539; called by muse, mutect2
- RALYL | c.669G>A p.Q223= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV101569148; called by muse, mutect2, varscan2
- RPL10L | c.633T>G p.V211= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV100022508; called by muse, mutect2, varscan2
- SATB2 | c.1947G>C p.S649= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as COSV99610463, COSV99611063; called by muse, mutect2, varscan2
- SLITRK4 | c.1359T>C p.Y453= | Silent (SNP) | VAF 20/28 reads (71%) | catalogued as COSV100567289; called by muse, mutect2, varscan2
- STAT3 | c.1926G>A p.K642= | Silent (SNP) | VAF 9/190 reads (5%) | catalogued as COSV99232687; called by muse, mutect2
- SYNE2 | c.11931A>T p.I3977= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV100647405; called by muse, mutect2, varscan2
- TAGAP | c.1449T>C p.N483= | Silent (SNP) | VAF 10/188 reads (5%) | catalogued as COSV100487394; called by muse, mutect2
- TCF25 | c.1332G>A p.R444= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV99642720; called by muse, mutect2, varscan2
- TFPI | c.12A>C p.T4= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV99258599; called by muse, mutect2, varscan2
- THSD1 | c.375G>T p.V125= | Silent (SNP) | VAF 31/97 reads (32%) | catalogued as COSV51630071, COSV99318848; called by muse, mutect2, varscan2
- TMEM255A | c.864G>T p.L288= | Silent (SNP) | VAF 36/66 reads (55%) | catalogued as COSV100550312; called by muse, mutect2, varscan2
- TOR1B | c.39G>T p.L13= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as COSV99400123; called by muse, mutect2, varscan2
- UNC13C | c.4794G>T p.L1598= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV99514013, COSV99515401; called by muse, mutect2, varscan2
- USH2A | c.15282G>A p.P5094= | Silent (SNP) | VAF 33/91 reads (36%) | catalogued as rs754800723, COSV56360800, COSV56368419; called by muse, mutect2, varscan2
- USP32 | c.4653G>A p.P1551= | Silent (SNP) | VAF 39/106 reads (37%) | catalogued as rs1142748, COSV56268095; called by muse, mutect2, varscan2
- UXS1 | c.837G>T p.L279= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as COSV99308147; called by muse, mutect2, varscan2
- VIM | c.717A>G p.E239= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV99813026; called by muse, mutect2, varscan2
- DCHS2 | n.6004C>G | RNA (SNP) | VAF 17/33 reads (52%) | catalogued as COSV100601585; called by muse, mutect2, varscan2
- PCARE | c.-1C>A | 5'UTR (SNP) | VAF 5/88 reads (6%) | called by muse, mutect2
- RPL5 | c.528-142G>C | Intron (SNP) | VAF 6/79 reads (8%) | catalogued as COSV100240343; called by muse, mutect2
- XIRP2 | c.*1272dup | 3'UTR (INS) | VAF 4/29 reads (14%) | called by mutect2, pindel
